Somatic mutation profile of cancer-model specimen HCM-CSHL-0062-C18-85A (3D Organoid; aliquot HCM-CSHL-0062-C18-85A-01D-A768-36), derived from the primary tumor of HCMI case HCM-CSHL-0062-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.6 years (25,784 days).
Specimen HCM-CSHL-0062-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2125632-d5f6-4757-a3c8-e53bbeb36a88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0062-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0062-C18-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02f6c415-798b-4e36-b62e-c29cb875b9cb

The open-access MAF lists 179 somatic variants for this specimen: 115 protein-altering or splice-affecting, 46 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 46, Nonsense Mutation 17, Intron 9, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 3, RNA 3, In Frame Del 3, 3'UTR 3, 5'UTR 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3549T>G p.Y1183* | Nonsense Mutation (SNP) | VAF 186/367 reads (51%) | catalogued as rs1561585641, COSV57333455; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 155/306 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 196/339 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 78/176 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs200621947; called by muse, mutect2, varscan2
- APC | c.1206del p.E403Kfs*51 | Frame Shift Del (DEL) | VAF 77/164 reads (47%) | catalogued as COSV57351508; called by mutect2, pindel, varscan2
- APCDD1L | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 97/256 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs923267133, COSV100953923; called by muse, mutect2, varscan2
- ATXN2 | c.3809C>T p.T1270M (on ENST00000550104; = p.T1110M on NM_002973.4) | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as rs1276087803; called by muse, mutect2, varscan2
- BCL9L | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV104403427; called by muse, mutect2, varscan2
- CBARP | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 146/277 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV99289524; called by muse, mutect2, varscan2
- CEP290 | c.4678C>T p.Q1560* | Nonsense Mutation (SNP) | VAF 153/413 reads (37%) | catalogued as rs1167696567; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2, varscan2
- CLIP2 | c.2285_2287del p.K762del | In Frame Del (DEL) | VAF 148/336 reads (44%) | catalogued as rs1273300405; called by pindel, varscan2
- CNKSR2 | c.2392G>A p.A798T | Missense Mutation (SNP) | VAF 139/248 reads (56%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs755412341, COSV54258773; called by muse, mutect2, varscan2
- CNNM1 | c.2176+1G>A p.X726_splice | Splice Site (SNP) | VAF 89/170 reads (52%) | catalogued as rs376631525; called by muse, mutect2, varscan2
- CNTN5 | c.3275C>A p.A1092E | Missense Mutation (SNP) | VAF 151/343 reads (44%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.505); catalogued as COSV54320087; called by muse, mutect2, varscan2
- CPE | c.1289C>A p.A430E | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.316); catalogued as rs1301681242, COSV101291606; called by muse, mutect2, varscan2
- CXorf56 | c.587C>T p.A196V (on ENST00000536133 / NM_001170570.2; = p.A210V on NM_022101.4) | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.281); catalogued as rs764134233, COSV100233328; called by muse, mutect2, varscan2
- DMBT1 | c.7441C>T p.R2481C (on ENST00000338354 / NM_001377530.1; = p.R1724C on NM_004406.3) | Missense Mutation (SNP) | VAF 209/411 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1034308642, COSV57533768; called by muse, mutect2, varscan2
- DNHD1 | c.9284C>T p.S3095L | Missense Mutation (SNP) | VAF 227/479 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs975437665, COSV54433720; called by muse, mutect2, varscan2
- DOK6 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 82/267 reads (31%) | catalogued as COSV101234236; called by muse, mutect2, varscan2
- ECE1 | c.2017G>A p.G673R | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1376227095, COSV51663176; called by muse, mutect2, varscan2
- EDA | c.408G>C p.L136F | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV100999627; called by muse, mutect2, varscan2
- EEF1G | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 185/409 reads (45%) | catalogued as COSV61323157; called by muse, mutect2, varscan2
- EPAS1 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 287/625 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1440594107; called by muse, mutect2, varscan2
- ERICH3 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377323449; called by muse, mutect2, varscan2
- FMR1 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 113/209 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.111); catalogued as rs1557182644, COSV54424209; called by muse, mutect2, varscan2
- GPER1 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 195/403 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223808410; called by muse, mutect2, varscan2
- HOXC13 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV54499996; called by muse, mutect2, varscan2
- IFT140 | c.2423C>T p.A808V | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs748463111, COSV54153601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INTS5 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs887202407; called by muse, mutect2, varscan2
- ITGB4 | c.4336C>T p.R1446W | Missense Mutation (SNP) | VAF 199/417 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs1299766746; called by muse, mutect2, varscan2
- JAKMIP2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 237/506 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs774610220, COSV54597568; called by muse, mutect2, varscan2
- KCNC2 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 120/421 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as rs757081755; called by muse, mutect2, varscan2
- KCNN2 | c.1641C>G p.Y547* (on ENST00000264773; = p.Y759* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 20/525 reads (4%) | catalogued as COSV53290368; called by muse, mutect2
- KIF21B | c.1212G>A p.A404= | Splice Region (SNP) | VAF 214/410 reads (52%) | catalogued as rs371524692; called by muse, mutect2
- LIN28A | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs749687753, COSV54261112; called by muse, mutect2, varscan2
- MBOAT1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752753742; called by muse, mutect2, varscan2
- MED12L | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 71/157 reads (45%) | catalogued as COSV56388924; called by muse, mutect2, varscan2
- MFAP5 | c.236dup p.N79Kfs*9 | Frame Shift Ins (INS) | VAF 83/409 reads (20%) | catalogued as rs746355340; called by mutect2, varscan2
- MICAL2 | c.948C>T p.N316= | Splice Region (SNP) | VAF 38/156 reads (24%) | catalogued as rs770956984; called by muse, mutect2, varscan2
- MYO19 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369758596; called by muse, mutect2, varscan2
- NBPF11 | c.122_123del p.R41Mfs*20 | Frame Shift Del (DEL) | VAF 144/538 reads (27%) | catalogued as rs1229366144; called by pindel, varscan2
- NRCAM | c.2359C>T p.R787C (on ENST00000379028 / NM_001371124.1; = p.R771C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 130/263 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769341831, COSV61043555; called by muse, mutect2, varscan2
- OLR1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs374494106, COSV100376305; called by muse, mutect2, varscan2
- OR4A15 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 176/320 reads (55%) | catalogued as rs150217199, COSV100123812; called by muse, mutect2, varscan2
- OR51M1 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs774673987, COSV60783885; called by muse, mutect2
- OR7D2 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 88/205 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.305); catalogued as rs767692324; called by muse, mutect2, varscan2
- PAX7 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 20/469 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1473016979, COSV64750307; called by muse, mutect2
- PCDH19 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 239/603 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM162899, COSV55271064, COSV99721011; called by muse, mutect2, varscan2
- PCDHA11 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 280/670 reads (42%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as COSV100250531; called by muse, mutect2, varscan2
- PCDHB14 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 331/1110 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); catalogued as COSV99505551; called by muse, mutect2, varscan2
- PCSK4 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs775454627, COSV52012379; called by muse, mutect2, varscan2
- PIK3CG | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 138/316 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1226994105, COSV63247193; called by muse, mutect2, varscan2
- PIP4K2C | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 148/654 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs973052423, COSV100533807; called by muse, mutect2, varscan2
- PSMA3 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99373520; called by muse, mutect2, varscan2
- PXDNL | c.2905G>A p.A969T | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as rs1461360955; called by muse, mutect2, varscan2
- RBM20 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 301/578 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs766868824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBMXL2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); catalogued as rs866421802; called by muse, mutect2, varscan2
- RBMXL3 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 112/225 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs1556560828; called by muse, mutect2, varscan2
- RHBDF2 | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 150/318 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1196107833, COSV99166265; called by muse, mutect2, varscan2
- RPRM | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 10/342 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV57988594; called by muse, mutect2
- TLR9 | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 59/105 reads (56%) | catalogued as rs1013859585, COSV62345876; called by muse, mutect2, varscan2
- TMEM132C | c.3100C>T p.R1034W | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs369408255, COSV59430525; called by muse, mutect2, varscan2
- USP6 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 276/725 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.713); catalogued as rs1419592864; called by muse, mutect2, varscan2
- WNT3 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 138/284 reads (49%) | catalogued as COSV56644576; called by muse, mutect2, varscan2
- AATK | c.3899G>A p.W1300* (on ENST00000326724 / NM_001080395.3; = p.W1197* on NM_004920.2) | Nonsense Mutation (SNP) | VAF 36/169 reads (21%) | called by muse, mutect2, varscan2
- ANKRD29 | c.712G>C p.G238R | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANOS1 | c.1063-1G>A p.X355_splice | Splice Site (SNP) | VAF 130/269 reads (48%) | called by muse, mutect2, varscan2
- AUTS2 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- BCL9 | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 71/141 reads (50%) | called by muse, mutect2, varscan2
- BRAF | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 107/309 reads (35%) | called by muse, mutect2, varscan2
- C8orf48 | c.396G>C p.L132F | Missense Mutation (SNP) | VAF 95/199 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CACNA2D1 | c.1172A>C p.Q391P | Missense Mutation (SNP) | VAF 132/324 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CFAP65 | c.3743G>T p.S1248I | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.27); called by mutect2, varscan2
- CFAP69 | c.2574A>T p.K858N | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2
- CNRIP1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CST6 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 87/169 reads (51%) | called by muse, mutect2, varscan2
- CYLC1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHTKD1 | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELMO3 | c.960dup p.I321Hfs*67 (on ENST00000652269; = p.I268Hfs*67 on NM_024712.5) | Frame Shift Ins (INS) | VAF 84/203 reads (41%) | called by mutect2, pindel, varscan2
- EPHA2 | c.1683-1G>T p.X561_splice | Splice Site (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- FOXD3 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 116/240 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- GON4L | c.2947C>T p.P983S | Missense Mutation (SNP) | VAF 206/421 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HGF | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HIC1 | c.928G>A p.G310S (on ENST00000322941 / NM_001098202.1; = p.G291S on NM_006497.4) | Missense Mutation (SNP) | VAF 28/592 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2
- HTRA1 | c.866A>G p.Q289R | Missense Mutation (SNP) | VAF 209/433 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IRAG2 | c.3857G>T p.G1286V (on ENST00000636465; = p.G331V on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- LPO | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 108/324 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LRP2 | c.7148C>T p.A2383V | Missense Mutation (SNP) | VAF 192/408 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRP4 | c.4357G>A p.E1453K | Missense Mutation (SNP) | VAF 68/552 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MAP9 | c.979A>G p.R327G | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MDN1 | c.4542dup p.F1515Ifs*12 | Frame Shift Ins (INS) | VAF 86/305 reads (28%) | called by mutect2, pindel, varscan2
- MTMR4 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MYCBP2 | c.5146C>T p.P1716S (on ENST00000357337; = p.P1754S on NM_015057.5) | Missense Mutation (SNP) | VAF 160/644 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NBEA | c.6726del p.D2243Ifs*5 | Frame Shift Del (DEL) | VAF 71/236 reads (30%) | called by mutect2, pindel, varscan2
- NPAS3 | c.2494G>A p.A832T (on ENST00000356141 / NM_001164749.2; = p.A800T on NM_022123.3) | Missense Mutation (SNP) | VAF 76/634 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ONECUT2 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 164/334 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); called by muse, varscan2
- OR2G6 | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 109/354 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- PLOD2 | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 104/235 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- PPP1R3A | c.185G>T p.R62I | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC24A4 | c.1220T>C p.V407A | Missense Mutation (SNP) | VAF 180/357 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORCS1 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX9 | c.367_378del p.L123_Q126del | In Frame Del (DEL) | VAF 78/182 reads (43%) | called by mutect2, pindel, varscan2
- SP100 | c.2279G>C p.G760A | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TACR3 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 133/268 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TAS1R2 | c.1132A>T p.R378W | Missense Mutation (SNP) | VAF 193/400 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TDRD15 | c.2998G>T p.E1000* | Nonsense Mutation (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- TMEM132B | c.1601G>A p.W534* | Nonsense Mutation (SNP) | VAF 19/410 reads (5%) | called by muse, mutect2
- TMUB2 | c.467A>G p.E156G (on ENST00000538716 / NM_001353177.2; = p.E136G on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 144/301 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- TNNI3K | c.2327G>A p.R776K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TOP2A | c.2548A>G p.I850V | Missense Mutation (SNP) | VAF 102/451 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRADD | c.268_291del p.Y90_A97del | In Frame Del (DEL) | VAF 117/317 reads (37%) | called by mutect2, pindel, varscan2
- TRPV3 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- TTI1 | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 290/411 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ACSS2 | c.105C>T p.V35= | Silent (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- ADAD2 | c.1413G>A p.P471= (on ENST00000315906 / NM_001145400.2; = p.P553= on NM_139174.4) | Silent (SNP) | VAF 137/283 reads (48%) | catalogued as rs1022671732, COSV99235229; called by muse, mutect2, varscan2
- ADAMTS9 | c.1974C>T p.D658= | Silent (SNP) | VAF 22/197 reads (11%) | catalogued as rs754577175, COSV55777195; called by muse, mutect2, varscan2
- AGGF1 | c.96G>A p.L32= | Silent (SNP) | VAF 274/521 reads (53%) | catalogued as rs751836536; called by muse, mutect2, varscan2
- ALG14 | c.30C>T p.A10= | Silent (SNP) | VAF 121/256 reads (47%) | called by muse, varscan2
- CHFR | c.1509G>A p.P503= (on ENST00000432561 / NM_001161345.1; = p.P462= on NM_018223.2) | Silent (SNP) | VAF 96/223 reads (43%) | catalogued as rs142511371; called by muse, mutect2, varscan2
- CHFR | c.492G>A p.S164= | Silent (SNP) | VAF 139/740 reads (19%) | catalogued as rs199790262, COSV57175231; called by muse, mutect2, varscan2
- COL4A6 | c.2364C>T p.H788= | Silent (SNP) | VAF 82/175 reads (47%) | catalogued as rs375971196, COSV57881919; called by muse, mutect2, varscan2
- COL9A1 | c.642T>A p.I214= | Silent (SNP) | VAF 12/286 reads (4%) | catalogued as COSV61829046; called by muse, mutect2
- DNAH17 | c.141C>T p.P47= | Silent (SNP) | VAF 207/401 reads (52%) | catalogued as rs370459386; called by muse, mutect2, varscan2
- DNAH9 | c.3249C>T p.G1083= | Silent (SNP) | VAF 228/461 reads (49%) | called by muse, mutect2, varscan2
- DRAXIN | c.708C>T p.T236= | Silent (SNP) | VAF 164/359 reads (46%) | catalogued as rs555747838; called by muse, mutect2, varscan2
- EMILIN2 | c.2478G>T p.L826= | Silent (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- FRYL | c.8658C>T p.S2886= | Silent (SNP) | VAF 58/115 reads (50%) | catalogued as rs375724636; called by muse, mutect2, varscan2
- IFNA1 | c.330C>T p.T110= | Silent (SNP) | VAF 71/213 reads (33%) | catalogued as rs774504120; called by muse, mutect2, varscan2
- INA | c.696C>T p.D232= | Silent (SNP) | VAF 138/306 reads (45%) | called by muse, mutect2, varscan2
- KLHL34 | c.1578C>T p.G526= | Silent (SNP) | VAF 53/98 reads (54%) | catalogued as COSV101069938; called by muse, mutect2, varscan2
- KRTAP23-1 | c.144A>G p.P48= | Silent (SNP) | VAF 226/526 reads (43%) | catalogued as COSV100492636; called by muse, mutect2, varscan2
- LCE1F | c.81G>A p.P27= | Silent (SNP) | VAF 176/321 reads (55%) | catalogued as rs759179642, COSV57668723; called by muse, mutect2, varscan2
- LILRB1 | c.198C>A p.T66= (on ENST00000427581; = p.T30= on NM_006669.6) | Silent (SNP) | VAF 58/219 reads (26%) | catalogued as rs540151068; called by muse, mutect2, varscan2
- MACF1 | c.15009G>T p.L5003= (on ENST00000372915; = p.L2936= on NM_012090.5) | Silent (SNP) | VAF 98/194 reads (51%) | called by muse, mutect2, varscan2
- MAGEC1 | c.3288T>C p.P1096= | Silent (SNP) | VAF 98/207 reads (47%) | called by muse, mutect2, varscan2
- MAN2C1 | c.207C>G p.V69= | Silent (SNP) | VAF 82/167 reads (49%) | called by muse, mutect2, varscan2
- MAP3K9 | c.2499G>A p.T833= (on ENST00000554752 / NM_001284230.1; = p.T847= on NM_033141.4) | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as rs572178360; called by muse, mutect2, varscan2
- MYBPC2 | c.1290C>T p.A430= | Silent (SNP) | VAF 61/113 reads (54%) | catalogued as rs749900428; called by muse, mutect2, varscan2
- NKX6-2 | c.639G>A p.S213= | Silent (SNP) | VAF 112/702 reads (16%) | called by muse, mutect2, varscan2
- NMNAT2 | c.378C>T p.I126= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as rs201999438; called by muse, mutect2, varscan2
- OLIG2 | c.51C>T p.P17= | Silent (SNP) | VAF 208/486 reads (43%) | called by muse, mutect2, varscan2
- P2RY8 | c.888G>A p.A296= | Silent (SNP) | VAF 271/546 reads (50%) | catalogued as COSV67177132; called by muse, mutect2, varscan2
- PCDHB3 | c.708C>T p.N236= | Silent (SNP) | VAF 7/168 reads (4%) | catalogued as rs782533944, COSV50564702; called by muse, mutect2
- PCSK6 | c.2187C>T p.C729= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as rs759858337, COSV61857061; called by muse, mutect2
- PDS5A | c.2787G>A p.R929= | Silent (SNP) | VAF 116/231 reads (50%) | called by muse, mutect2, varscan2
- POLR1A | c.3558G>A p.E1186= | Silent (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- PRR23A | c.387C>T p.G129= | Silent (SNP) | VAF 162/326 reads (50%) | catalogued as rs368434952; called by muse, mutect2, varscan2
- RSPRY1 | c.1200G>T p.A400= | Silent (SNP) | VAF 118/266 reads (44%) | called by muse, mutect2, varscan2
- SARDH | c.522G>A p.A174= | Silent (SNP) | VAF 87/187 reads (47%) | called by muse, mutect2
- SMO | c.807C>T p.Y269= | Silent (SNP) | VAF 19/159 reads (12%) | catalogued as rs200677912, COSV99977207; called by muse, mutect2, varscan2
- SOWAHD | c.81G>A p.P27= | Silent (SNP) | VAF 108/210 reads (51%) | called by muse, mutect2, varscan2
- TENM1 | c.2928C>T p.C976= | Silent (SNP) | VAF 88/469 reads (19%) | catalogued as rs1438862548, COSV64436902; called by muse, mutect2, varscan2
- TLNRD1 | c.546G>A p.E182= | Silent (SNP) | VAF 99/179 reads (55%) | catalogued as rs572653982; called by muse, mutect2, varscan2
- TRIM71 | c.336C>T p.S112= | Silent (SNP) | VAF 55/789 reads (7%) | catalogued as rs1234421973; called by muse, mutect2
- TYW5 | c.69C>G p.L23= | Silent (SNP) | VAF 69/134 reads (51%) | called by muse, mutect2, varscan2
- VWA3A | c.285G>A p.S95= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as rs1357123728; called by muse, mutect2
- WDR18 | c.516G>A p.A172= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as rs1007494180, COSV99242635; called by muse, mutect2, varscan2
- ZFP64 | c.522C>T p.P174= | Silent (SNP) | VAF 26/222 reads (12%) | called by muse, mutect2, varscan2
- ZNF521 | c.3037T>C p.L1013= | Silent (SNP) | VAF 67/133 reads (50%) | called by muse, mutect2, varscan2
- ANO1 | c.2198-823G>A | Intron (SNP) | VAF 28/57 reads (49%) | catalogued as rs1368114518; called by muse, mutect2, varscan2
- AP001122.1 | n.609C>T | RNA (SNP) | VAF 12/131 reads (9%) | called by muse, mutect2
- ARHGEF25 | chr12:57610631 G>T | 5'Flank (SNP) | VAF 38/128 reads (30%) | called by muse, mutect2, varscan2
- BCAT1 | c.7-1083C>T | Intron (SNP) | VAF 92/251 reads (37%) | called by muse, mutect2, varscan2
- CD81 | c.67-3809G>A | Intron (SNP) | VAF 58/258 reads (22%) | catalogued as rs1360262452; called by muse, mutect2, varscan2
- FOXP2 | c.*3151T>G | 3'UTR (SNP) | VAF 119/227 reads (52%) | called by muse, mutect2, varscan2
- GRIK1 | c.1251+146A>G | Intron (SNP) | VAF 130/272 reads (48%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1377+40C>T | Intron (SNP) | VAF 150/433 reads (35%) | catalogued as rs746545872; called by muse, mutect2, varscan2
- MAU2 | c.*53C>T | 3'UTR (SNP) | VAF 264/545 reads (48%) | catalogued as rs940624920; called by muse, mutect2, varscan2
- NAA60 | c.*207-40G>A | Intron (SNP) | VAF 51/134 reads (38%) | catalogued as rs766364207; called by muse, mutect2, varscan2
- PAX3 | c.-20C>T | 5'UTR (SNP) | VAF 137/275 reads (50%) | catalogued as rs1469006207, COSV51345776; called by muse, mutect2, varscan2
- POLA1 | c.2947-21311G>A | Intron (SNP) | VAF 141/360 reads (39%) | catalogued as rs1370942836, COSV66891326; called by muse, mutect2, varscan2
- PRICKLE3 | c.43-40G>A | Intron (SNP) | VAF 153/277 reads (55%) | called by muse, mutect2, varscan2
- PRPF8 | c.3774+11G>A | Intron (SNP) | VAF 186/426 reads (44%) | catalogued as rs762203625; called by muse, mutect2, varscan2
- SLC9A3R2 | c.*513C>T | 3'UTR (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- TCP10L3 | n.469C>T | RNA (SNP) | VAF 146/466 reads (31%) | catalogued as rs1190388784; called by muse, varscan2
- TNFRSF8 | c.-51G>A | 5'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- ZNF971P | n.335T>G | RNA (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
